Somatic mutation profile of tumor specimen TARGET-10-PATSLH-09A (aliquot TARGET-10-PATSLH-09A-01D) from TARGET case TARGET-10-PATSLH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (824 days).
Specimen TARGET-10-PATSLH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8afa051-23a3-4537-b90b-d87c6a114696.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATSLH-10A (Blood Derived Normal), aliquot TARGET-10-PATSLH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4824558-7c8b-4977-abe3-61afd403d9bc

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP9 | c.1532G>A p.R511H (on ENST00000393797 / NM_001319850.2; = p.R492H on NM_032496.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs143954280; called by muse, mutect2, varscan2
- CCND3 | c.605T>C p.M202T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57828927; called by muse, mutect2, varscan2
- DDX3X | c.1057G>A p.D353N (on ENST00000399959; = p.D354N on NM_001356.5) | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863073, COSV67863895, COSV67863993; called by muse, mutect2, varscan2
- DDX4 | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV61755838; called by muse, mutect2, varscan2
- GATA3 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60516183; called by muse, mutect2, varscan2
- HOXD3 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV50882143; called by muse, mutect2, varscan2
- PKHD1 | c.8909_8912del p.F2970Wfs*68 | Frame Shift Del (DEL) | VAF 31/80 reads (39%) | catalogued as rs1473686155; called by mutect2, pindel, varscan2
- HMGB1 | c.13_16dup p.P6Rfs*3 | Frame Shift Ins (INS) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- HMGCLL1 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- KPNA7 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- KIF1A | c.4827C>T p.R1609= (on ENST00000320389 / NM_001379639.1; = p.R1601= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- PTK2B | c.988-59G>T | Intron (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
